Surgical pathology report (de-identified scan), TCGA case TCGA-73-7498, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-7498-01A (Primary Tumor).

[page 1 of 3]
TSS: [REDACTED]

SPECIMENS:

- A. 4R RIGHT PARATRACHEAL LYMPH NODE
- B. LEVEL 7 LYMPH NODE
- C. RIGHT LOWER LOBE WEDGE
- D. LEVEL 8 LYMPH NODE
- E. LEVEL 9 LYMPH NODE
- F. RIGHT LOWER LOBE

SPECIMEN(S):

- A. 4R RIGHT PARATRACHEAL LYMPH NODE
- B. LEVEL 7 LYMPH NODE
- C. RIGHT LOWER LOBE WEDGE
- D. LEVEL 8 LYMPH NODE
- E. LEVEL 9 LYMPH NODE
- F. RIGHT LOWER LOBE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA, Lymph node, 4R right paratracheal, biopsy: Negative for malignancy

FSB, Lymph node, level 7, biopsy: Negative for malignancy

FSC, Lung, right lower lobe, wedge biopsy: Positive for malignancy non-small cell carcinoma, favor adenocarcinoma, diagnoses called at [REDACTED] and [REDACTED] by [REDACTED]

FSF, lung, right lower, lobectomy: Bronchial margin negative for malignancy, diagnosis called at [REDACTED] by [REDACTED]

DIAGNOSIS:

A. LYMPH NODE, RIGHT PARATRACHEAL – 4R, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

B. LYMPH NODE, LEVEL 7, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

C. LUNG, RIGHT LOWER LOBE, WEDGE RESECTION:
- ADENOCARCINOMA, MODERATELY DIFFERENTIATED WITH BRONCHIOLOALVEOLAR FEATURES
- 2.5 CM IN GREATEST DIMENSION
- 1.8 X 1.0 CM IN ADDITIONAL DIMENSIONS
- THE PLEURAL SURFACE IS NEGATIVE FOR TUMOR
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- MILD EMPHYSEMATOUS CHANGES

D. LYMPH NODE, LEVEL 8, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

E. LYMPH NODE, LEVEL 9, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

F. LUNG, RIGHT LOWER LOBE, COMPLETION LOBECTOMY:
- SEPARATE MICROSCOPIC FOCUS OF ADENOCARCINOMA, BRONCHIOLOALVEOLAR TYPE
- 0.9 CM IN GREATEST DIMENSION (MEASURED MICROSCOPICALLY)
- THE PLEURAL SURFACE IS NEGATIVE FOR TUMOR.
- THE BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR.
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- PLEURAL PLAQUE
- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES (0/2).
- MILD EMPHYSEMATOUS CHANGES

COMMENT: Two tumors are identified. The tumor in part C was identified grossly, and the tumor in part F was only identified microscopically. These tumors are consistent with synchronous primary tumors, and the tumor in part C will be used for the synoptic report. This case was shown to [REDACTED] and he agrees.

[page 2 of 3]
TSS: [REDACTED]

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: C: RIGHT LOWER LOBE WEDGE

Surgical Procedure: Lobectomy

Laterality: Right

Tumor Site: Lower lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 2.5cm

Additional dimensions: 1.8cm x 1cm

WHO CLASSIFICATION

Adenocarcinoma

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)

Negative 0 / 2

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)

Negative 0 / 4

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular

N/A

Non-Neoplastic Lung: Emphysematous changes

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 1b N 0 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. 4R RIGHT PARATRACHEAL LYMPH NODE

Received fresh labeled with the patient's identification and designated "4R right paratracheal lymph node" is a fragment of tan-pink to anthracotic soft tissue measuring 1 x 0.5 and 0.2-cm. Specimen is bisected. Touch preparation performed. Submitted entirely for frozen section, FSA.

B. LEVEL 7 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 7 lymph node" is a fragment of tan-pink soft tissue measuring 0.7 x 0.5 x 0.2 cm. Specimen is bisected. Touch preparation performed. Submitted entirely for frozen section, FSB.

C. RIGHT LOWER LOBE WEDGE

Received fresh labeled with the patient's identification and designated "right lower lobe wedge" is a stapled wedge of lung tissue weighing 15 g and measuring 6.5 x 3 x 2 cm. The pleural surface inked black, staple line inked blue. Sectioning shows a firm ill-defined tan mass measuring 2.5 x 1.8 x 1 cm, located 0.5-cm from the stapled margin. A portion of the specimen is submitted for tissue procurement.

The specimen representatively submitted:

FSC1: Mass, frozen section sample

C2: Remainder of mass and pleural surface

C3: Uninvolved lung parenchyma

D. LEVEL 8 LYMPH NODE

Received in formalin labeled with the patient's identification and designated "level 8 lymph node" is a fragment of yellow-tan soft tissue measuring 0.6 x 0.3 x 0.2 cm. Entirely submitted, D1.

E. LEVEL 9 LYMPH NODE

Received in formalin labeled with the patient's identification and designated "level 9 lymph node" is a fragment of red-tan soft tissue measuring 0.8 x 0.5 x 0.2 cm. Entirely submitted, E1.

F. RIGHT LOWER LOBE

Received fresh labeled with the patient's identification and designated "right lower lobe" is the resected lobectomy specimen weighing 182 g and measuring 13.5 x 11 x 3 cm. The pleural surface

[page 3 of 3]
TSS: [REDACTED]

demonstrates two 0.3-cm plaque like areas, both located approximately 4-cm from the bronchial margin. Sectioning shows deep red consolidated lung parenchyma. No lesions or nodules are grossly appreciated. A portion of the specimen is submitted for tissue procurement. The specimen is representatively submitted:

FSF1: Shaved bronchial margin

F2: Plaque like areas, entirely submitted

F3: Possible peribronchial lymph nodes

F4-F5: Random sections lung parenchyma

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right lower lobe lung nodule

[REDACTED]

Source: NCI Genomic Data Commons file 459a7eb5-7350-4880-9588-71036ad37995 (TCGA-73-7498.C60CA2D8-4981-406A-9B8D-8EFDE4976001.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).